Gene-level copy-number profile of tumor specimen TCGA-DU-7014-01A from TCGA case TCGA-DU-7014, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 59.9 years (21,865 days).
Specimen TCGA-DU-7014-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.d4f483ce-9a21-4e4d-92fe-76048efac0bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-7014-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30e7fd6f-645a-4f25-a8d3-d40c1e348bdf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,208; copy number 2: 122; copy number 3: 11,367; copy number 4: 39,443; copy number 5: 3,860; copy number 6: 711; copy number 7: 2,100.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-7014-01A-11D-2023-01): tumor purity 0.77, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
